Gene-level copy-number profile of tumor specimen TCGA-GV-A40E-01A from TCGA case TCGA-GV-A40E, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.5 years (27,569 days).
Specimen TCGA-GV-A40E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.f062a199-bef1-475d-b874-ba04e87fcf9d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GV-A40E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40d7a65e-0e00-4add-b68e-4967ad733588

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 6; copy number 2: 3,671; copy number 3: 21,195; copy number 4: 21,247; copy number 5: 6,122; copy number 6: 4,568; copy number 7: 1,409; copy number 8: 1,047; copy number 9: 32; copy number 10: 134; copy number 12: 71; copy number 13: 21; copy number 14: 24; copy number 18: 87; copy number 21: 4; copy number 22: 8; copy number 23: 39; copy number 25: 32; copy number 27: 4; copy number 30: 3; copy number 35: 46; copy number 39: 1; copy number 50: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GV-A40E-01A-12D-A23L-01): tumor purity 0.34, ploidy 5.52, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:78,880,713–79,185,523, 9 genes: AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1.
- chr14:25,267,064–27,295,516, 17 genes (within-gene range 0–3): HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 525 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:12,406,486–15,113,221, 36 genes, copy number 10: RN7SKP293, RPL15P3, LINC02530, PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P.
- chr6:15,522,195–23,031,780, 93 genes, copy number 13–25 (broad region; genes not listed).
- chr6:67,210,408–69,389,506, 16 genes, copy number 9 (within-gene range 3–14): AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, ADGRB3.
- chr6:137,823,673–140,898,381, 45 genes, copy number 10 (within-gene range 7–10): WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865, RPSAP42, PERP, ARFGEF3, PBOV1, SMIM28, AL031003.1, MARCKSL1P2, HEBP2, NHSL1, MIR3145, AL391669.1, AL590617.1, AL590617.2, CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB, AL592429.2, AL592429.1, CITED2, LINC01625, ATP5PBP6, AL390205.1, FILNC1, AL050338.1, AL050338.2, AL357146.1, RNA5SP220, MIR3668, AL035446.2, MIR4465, RPS3AP24, AL035446.1.
- chr6:143,450,805–144,853,034, 23 genes, copy number 12 (within-gene range 3–12): PEX3, AL031320.2, VDAC1P8, FUCA2, PHACTR2, PHACTR2-AS1, AL049844.1, LTV1, AL049844.3, AL049844.2, ZC2HC1B, PLAGL1, HYMAI, AL109755.2, AL109755.1, SF3B5, MRPL42P3, STX11, TPT1P4, AL024474.1, UTRN, AL024474.2, AL590704.1.
- chr8:99,873,200–100,131,268, 5 genes, copy number 9 (within-gene range 6–9): COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1.
- chr8:100,831,728–102,688,906, 50 genes, copy number 12–39: RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2, MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, AP002851.1, ADI1P2.
- chr8:104,478,539–108,083,642, 37 genes, copy number 10–21: AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4.
- chr8:125,648,327–126,008,930, 1 gene, copy number 22 (within-gene range 5–22): AC016074.2.
- chr8:125,859,721–128,564,679, 43 genes, copy number 18–22: LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr11:12,261,426–12,989,597, 11 genes, copy number 9 (within-gene range 3–9): AC079329.1, AC025300.1, PARVA, AC009806.1, AC107881.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958.
- chr11:13,610,363–14,273,691, 15 genes, copy number 12–18: HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1.
- chr11:60,455,846–61,398,863, 39 genes, copy number 23: MS4A1, MS4A12, MS4A13, MS4A19P, LINC00301, MS4A8, MS4A18, MS4A15, MS4A10, AP000777.1, AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1, PGA3, PGA4, AP003037.1, PGA5, VWCE, DDB1, TKFC, CYB561A3, AP003108.3, TMEM138, TMEM216.
- chr11:97,222,644–97,259,987, 1 gene, copy number 27: LINC02553.
- chr11:100,336,856–104,164,379, 66 genes, copy number 30–50 (broad region; genes not listed).
- chr22:36,281,280–36,387,967, 1 gene, copy number 10 (within-gene range 5–10): MYH9.
- chr22:36,335,421–36,776,256, 16 genes, copy number 10: Z82215.1, FO393418.1, RPS15AP38, Y_RNA, AL022313.2, TXN2, FOXRED2, EIF3D, AL022313.1, AL022313.3, CACNG2, AL022313.4, AL049749.1, Z80897.2, IFT27, Z80897.1.
- chr22:38,426,327–38,924,708, 27 genes, copy number 10 (within-gene range 5–10): KCNJ4, Z97056.3, KDELR3, DDX17, DMC1, RPS29P31, FAM227A, CBY1, AL021707.4, AL021707.2, AL021707.9, TOMM22, JOSD1, GTPBP1, PRDX3P1, AL021707.5, SUN2, AL021707.3, AL021707.8, AL021707.1, AL021707.6, AL021707.7, DNAL4, NPTXR, CBX6, AL022318.5, AL022318.1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
